Somatic mutation profile of tumor specimen TCGA-HT-8104-01A (aliquot TCGA-HT-8104-01A-11D-2395-08) from TCGA case TCGA-HT-8104, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 51.3 years (18,748 days).
Specimen TCGA-HT-8104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9685b752-b24e-4394-9816-73165cd6a6b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8104-10A (Blood Derived Normal), aliquot TCGA-HT-8104-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d77e8faf-299f-434e-a33a-f97bd03a6a43

The open-access MAF lists 58 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Nonsense Mutation 5, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61754760; called by muse, mutect2, varscan2
- ADCY4 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs374008973; called by muse, mutect2, varscan2
- AKAP17A | c.1862G>A p.R621Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.018); catalogued as rs1355024842, COSV58310036; called by muse, mutect2, varscan2
- ASB7 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 31/79 reads (39%) | catalogued as COSV58403889; called by muse, mutect2, varscan2
- ATP1A2 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1274611333, COSV63404080; called by muse, mutect2, varscan2
- BCORL1 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.118); catalogued as COSV54397791; called by muse, mutect2, varscan2
- C8A | c.1414A>T p.S472C | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV63484605; called by muse, varscan2
- COL6A3 | c.5822C>T p.S1941L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as rs778288464, COSV55083269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPXCR1 | c.854T>A p.F285Y | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV52162648; called by muse, mutect2, varscan2
- CYLC1 | c.1860G>T p.K620N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100255115, COSV61412663; called by muse, mutect2, varscan2
- CYP1A2 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs759912942, COSV59659875; called by muse, mutect2, varscan2
- EGFR | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 128/2145 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1051753269, COSV51788393; ClinVar: not provided; called by muse, mutect2
- FAT2 | c.6349C>T p.R2117* | Nonsense Mutation (SNP) | VAF 64/210 reads (30%) | catalogued as rs753274186, COSV55818162; called by muse, mutect2, varscan2
- GABRA4 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV51923763; called by muse, mutect2, varscan2
- GATA6 | c.209C>A p.A70E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV52526004, COSV52526916; called by muse, mutect2
- GRK7 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs764098462, COSV53822831; called by muse, mutect2, varscan2
- IFT140 | c.4117A>G p.I1373V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1191743462, COSV63698173; called by muse, mutect2, varscan2
- IGSF1 | c.1383A>C p.Q461H | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV63837809; called by muse, mutect2, varscan2
- KDR | c.2830C>T p.R944* | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as COSV55766825, COSV55768653; called by muse, mutect2, varscan2
- KIAA0232 | c.3215C>T p.P1072L | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745376614, COSV56925871; called by muse, mutect2, varscan2
- LNX1 | c.2134C>T p.L712F (on ENST00000263925 / NM_001126328.3; = p.L616F on NM_032622.2) | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as rs1244545430, COSV55786536; called by muse, mutect2, varscan2
- LRP2 | c.9868C>T p.R3290C | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs144973875; called by muse, mutect2, varscan2
- MAP2 | c.1660A>G p.T554A | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV52293544; called by muse, mutect2
- MUC6 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs1191819314, COSV70142835; called by muse, varscan2
- NKRF | c.1372A>G p.T458A | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV58661778; called by muse, mutect2, varscan2
- NLRP11 | c.620G>C p.W207S | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100789787, COSV64087658; called by muse, mutect2, varscan2
- NMBR | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs769399701, COSV57801524; called by muse, mutect2, varscan2
- PGM5 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as COSV67162889; called by muse, varscan2
- PML | c.758C>A p.A253D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.702); catalogued as COSV51447535; called by muse, mutect2, varscan2
- PTEN | c.75G>T p.L25F | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs786201506, CM110137, COSV64289219, COSV64297774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIPK4 | c.2485C>T p.R829* (on ENST00000352483; = p.R781* on NM_020639.3) | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as rs749811219, COSV60187781; called by muse, mutect2
- RNASEH2A | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs369355807, COSV99677378; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs756961463, COSV55113657; called by muse, mutect2, varscan2
- RPF1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772841146, COSV65705876; called by muse, mutect2, varscan2
- RPS4X | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV60181687, COSV60181707; called by muse, mutect2, varscan2
- SF3B1 | c.1993A>T p.I665F | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59215739; called by muse, mutect2, varscan2
- SLC25A14 | c.595-1G>A p.X199_splice | Splice Site (SNP) | VAF 41/138 reads (30%) | catalogued as COSV54418459; called by muse, mutect2, varscan2
- SPEF2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs370674250; called by muse, mutect2, varscan2
- THSD7B | c.3739G>A p.V1247M (on ENST00000272643; = p.V1245M on NM_001316349.2) | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs370520413; called by muse, mutect2, varscan2
- TLX3 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51540276; called by muse, mutect2, varscan2
- TTC27 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs1044898848, COSV58652942; called by muse, mutect2, varscan2
- WSCD2 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as rs902011314, COSV54583827; called by muse, mutect2, varscan2
- ZMYM3 | c.3080C>G p.T1027S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.05); catalogued as COSV58738291, COSV58740050; called by muse, mutect2, varscan2
- ZNF665 | c.1537G>C p.A513P (on ENST00000600412; = p.A578P on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201975096; called by muse, mutect2, varscan2
- ZNF683 | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760028437, COSV62874548; called by muse, mutect2, varscan2
- AMFR | c.1860C>T p.D620= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV51922007; called by muse, mutect2, varscan2
- CACNA2D4 | c.891C>T p.D297= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs757244098, COSV54951426; called by muse, mutect2, varscan2
- DNAH3 | c.4770G>A p.S1590= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs536529487, COSV54526268; called by muse, mutect2, varscan2
- EBF1 | c.1044C>T p.N348= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs146276323; called by muse, mutect2, varscan2
- EPC2 | c.1401A>G p.T467= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV51544772; called by muse, mutect2, varscan2
- FAM71B | c.1125G>A p.A375= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs777781639, COSV57229393; called by muse, mutect2, varscan2
- FASLG | c.210C>A p.P70= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs775115804, COSV60680238; called by muse, mutect2, varscan2
- GDF10 | c.1164C>T p.I388= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs782733030; called by muse, mutect2
- IGSF1 | c.1677G>A p.G559= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs1320736669, COSV63837933; called by muse, mutect2, varscan2
- MYH13 | c.3300C>T p.D1100= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs757263442, COSV52830965; called by muse, mutect2, varscan2
- OR2G6 | c.597C>T p.L199= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV100598337, COSV58573901; called by muse, mutect2, varscan2
- TRHDE | c.1500C>T p.D500= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as rs748939724, COSV53837777; called by muse, mutect2, varscan2
- WASF4P | n.1339T>C | RNA (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
